Somatic mutation profile of tumor specimen TCGA-AG-A032-01A (aliquot TCGA-AG-A032-01A-01W-A00E-09) from TCGA case TCGA-AG-A032, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68.1 years (24,865 days).
Specimen TCGA-AG-A032-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b623732-d01c-4db4-9775-6b445e0d36c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A032-10A (Blood Derived Normal), aliquot TCGA-AG-A032-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f1ca63a-0901-401c-b465-720a664abda9

The open-access MAF lists 79 somatic variants for this specimen: 60 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 16, Nonsense Mutation 11, RNA 3, Frame Shift Del 1, Splice Site 1, In Frame Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 130/283 reads (46%) | catalogued as rs137854568, CM910029, COSV57324169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 14/25 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6140C>T p.A2047V (on ENST00000272895 / NM_173076.3; = p.A1729V on NM_015657.3) | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs755491703, COSV55964787; called by muse, mutect2
- ADAM29 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs748303748, COSV63668726; called by muse, mutect2
- ADGRL3 | c.2089C>T p.R697C (on ENST00000506720 / NM_001322402.2; = p.R629C on NM_015236.6) | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761017943, COSV72229893; called by muse, mutect2, varscan2
- ADI1 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100537876; called by muse, mutect2
- ANK2 | c.11134G>A p.V3712I | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs146476345; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 88/291 reads (30%) | catalogued as COSV57325414, COSV57354660, COSV57393116, COSV99964740; called by muse, mutect2, varscan2
- ARID2 | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57598812; called by muse, mutect2, varscan2
- CCAR2 | c.1532C>A p.A511E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV52383479; called by muse, mutect2
- CCDC136 | c.3442T>C p.W1148R | Missense Mutation (SNP) | VAF 280/691 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52797275; called by muse, mutect2, varscan2
- CDH18 | c.1766G>T p.C589F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56908106; called by muse, mutect2, varscan2
- CPNE4 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs373479979; called by muse, mutect2, varscan2
- DACH2 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146920220, COSV64163926; called by muse, mutect2, varscan2
- DCTN2 | c.629A>G p.H210R (on ENST00000548249 / NM_001261413.2; = p.H215R on NM_006400.4) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV63073426; called by muse, mutect2, varscan2
- DLEC1 | c.5020+2T>C p.X1674_splice | Splice Site (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100086625; called by muse, mutect2, varscan2
- DMD | c.5824G>A p.A1942T | Missense Mutation (SNP) | VAF 55/63 reads (87%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.475); catalogued as rs977284401, COSV63740787; called by muse, mutect2, varscan2
- DMRTB1 | c.986C>A p.S329* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV101008267; called by muse, mutect2, varscan2
- EEA1 | c.1543C>G p.L515V | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV59283538; called by muse, mutect2, varscan2
- FNDC1 | c.4825C>T p.R1609* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as rs759637752, COSV51933018; called by muse, mutect2, varscan2
- FRG2B | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 12/111 reads (11%) | catalogued as rs1484492169; called by muse, mutect2
- GABBR2 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52294276; called by muse, varscan2
- GABBR2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99412076; called by muse, varscan2
- GFRA1 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs191814086; called by muse, mutect2
- JAML | c.409C>A p.P137T (on ENST00000356289 / NM_001098526.2; = p.P127T on NM_153206.3) | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99409809; called by muse, mutect2
- KCNJ1 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.748); catalogued as COSV60661473; called by muse, mutect2, varscan2
- KRT73 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV59838288, COSV59838307; called by muse, mutect2, varscan2
- L3MBTL1 | c.2365G>C p.E789Q (on ENST00000418998 / NM_001377303.1; = p.E699Q on NM_015478.7) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV100917078; called by muse, mutect2, varscan2
- LRRC30 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV101274466, COSV67301458; called by muse, mutect2, varscan2
- MACROD2 | c.775G>T p.E259* (on ENST00000642719; = p.D259Y on NM_080676.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 208/549 reads (38%) | catalogued as rs1384663176, COSV53957342; called by muse, mutect2, varscan2
- MTTP | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs201863511, COSV55504491; called by muse, mutect2, varscan2
- MUSK | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 26/762 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV99504519, COSV99505363; called by muse, mutect2
- NECTIN4 | c.1522C>A p.H508N | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100920065; called by muse, mutect2
- NFX1 | c.1427C>A p.T476K | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59308824; called by muse, mutect2, varscan2
- OPCML | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs148167692, COSV59410223, COSV59453522; called by muse, mutect2, varscan2
- OR12D3 | c.494G>T p.S165I | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.482); catalogued as COSV65826800; called by muse, mutect2, varscan2
- PCDHGB1 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 37/92 reads (40%) | catalogued as COSV99549841; called by muse, mutect2, varscan2
- PLEKHA3 | c.251G>A p.W84* | Nonsense Mutation (SNP) | VAF 23/98 reads (23%) | catalogued as COSV52293419; called by muse, mutect2, varscan2
- PON1 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 81/232 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); catalogued as rs564064745, COSV55931007; called by muse, mutect2, varscan2
- PRAMEF4 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 617/745 reads (83%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs562920609, COSV52437653; called by muse, mutect2, varscan2
- PRKCG | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs764159841, COSV54725345; called by muse, mutect2, varscan2
- PRSS48 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV71613609; called by mutect2, varscan2
- SCNN1G | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs780133768, COSV55597599; called by muse, mutect2, varscan2
- SLF2 | c.3120G>T p.Q1040H | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53271575; called by muse, mutect2, varscan2
- SVEP1 | c.5690C>T p.P1897L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs761778704, COSV52836798, COSV99930203; called by muse, mutect2, varscan2
- SYT10 | c.308C>G p.A103G | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV57338493, COSV99951466; called by muse, mutect2, varscan2
- TAAR6 | c.9C>A p.S3R | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs868080405, COSV51582901; called by muse, mutect2, varscan2
- TCF7L2 | c.1219C>T p.R407* (on ENST00000355995 / NM_001367943.1; = p.R384* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 90/223 reads (40%) | catalogued as COSV53338146; called by muse, mutect2, varscan2
- THAP9 | c.1427A>C p.N476T | Missense Mutation (SNP) | VAF 114/435 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs775674355, COSV56355882; called by muse, mutect2, varscan2
- TSHZ3 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs745308178, COSV53666617; called by muse, mutect2, varscan2
- TTN | c.35495A>C p.K11832T (on ENST00000591111; = p.K10905T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | PolyPhen benign (0.354); catalogued as COSV59935190; called by muse, mutect2, varscan2
- TTN | c.12922C>A p.L4308I (on ENST00000591111; = p.L4262I on NM_003319.4) | Missense Mutation (SNP) | VAF 74/307 reads (24%) | catalogued as COSV59935196, COSV60407235; called by muse, mutect2, varscan2
- UBE2NL | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs782151716; called by muse, mutect2, varscan2
- UIMC1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779796802, COSV65893244; called by muse, mutect2, varscan2
- UPB1 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 31/127 reads (24%) | catalogued as rs1319553754, COSV58112499; called by muse, mutect2, varscan2
- ZNF100 | c.776A>T p.K259I | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99974447; called by muse, mutect2
- ZNF43 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV100732007; called by muse, mutect2
- COX18 | c.823_828dup p.P275_S276dup | In Frame Ins (INS) | VAF 14/41 reads (34%) | called by mutect2, varscan2
- XPR1 | c.1741_1751delinsAAA p.S581Kfs*17 | Frame Shift Del (DEL) | VAF 57/161 reads (35%) | called by pindel, varscan2*
- ANAPC5 | c.195G>A p.L65= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1555275450, COSV55841825; called by muse, mutect2
- CHFR | c.276G>A p.K92= | Silent (SNP) | VAF 12/247 reads (5%) | catalogued as rs1409273260, COSV99905878; called by muse, mutect2
- CXCR2 | c.333C>A p.G111= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as COSV59280002; called by muse, mutect2, varscan2
- GPR141 | c.306G>A p.T102= | Silent (SNP) | VAF 90/280 reads (32%) | catalogued as rs770328102, COSV57731662; called by muse, mutect2, varscan2
- GRIK3 | c.540C>T p.D180= | Silent (SNP) | VAF 70/112 reads (63%) | catalogued as rs377438243, COSV66136715; called by muse, mutect2, varscan2
- GRM1 | c.2334C>T p.P778= | Silent (SNP) | VAF 102/425 reads (24%) | catalogued as rs138085475; called by muse, mutect2, varscan2
- GRM5 | c.2307C>T p.N769= | Silent (SNP) | VAF 51/208 reads (25%) | catalogued as rs756305519, COSV59592302; called by muse, mutect2, varscan2
- GUCY1A1 | c.435C>T p.Y145= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as rs746076360, COSV56650005; called by muse, mutect2, varscan2
- MAJIN | c.576C>T p.G192= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV54164193; called by muse, mutect2, varscan2
- NOLC1 | c.2040C>T p.G680= | Silent (SNP) | VAF 119/318 reads (37%) | catalogued as COSV64180114; called by muse, mutect2, varscan2
- P4HA3 | c.639A>G p.G213= | Silent (SNP) | VAF 168/330 reads (51%) | catalogued as COSV59041181; called by muse, mutect2, varscan2
- PCDHA6 | c.525C>T p.S175= | Silent (SNP) | VAF 50/109 reads (46%) | catalogued as COSV100972668; called by muse, mutect2, varscan2
- SIMC1 | c.663C>T p.S221= (on ENST00000443967 / NM_001308196.1; = p.S240= on NM_001308195.2) | Silent (SNP) | VAF 91/280 reads (33%) | catalogued as rs529638463, COSV100366144; called by muse, mutect2, varscan2
- SLC2A3 | c.555G>A p.P185= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as rs762586293, COSV50001082; called by muse, mutect2, varscan2
- TENM2 | c.1158C>A p.L386= (on ENST00000518659 / NM_001122679.2; = p.L195= on NM_001080428.3) | Silent (SNP) | VAF 31/207 reads (15%) | catalogued as COSV101318491, COSV69124829; called by muse, mutect2, varscan2
- WEE2 | c.267C>T p.L89= | Silent (SNP) | VAF 80/773 reads (10%) | catalogued as COSV66878432; called by muse, mutect2
- DCHS2 | n.3605C>T | RNA (SNP) | VAF 144/584 reads (25%) | catalogued as COSV59720667; called by muse, mutect2
- KIR3DX1 | n.633C>A | RNA (SNP) | VAF 10/200 reads (5%) | catalogued as COSV99683805; called by muse, mutect2
- OR3A4P | n.1250G>A | RNA (SNP) | VAF 33/139 reads (24%) | catalogued as rs766433554; called by muse, mutect2, varscan2
